Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A5EO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A5EO-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					Male	Caucasian (White)	Melanoma		Skin	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Melanoma	n/a	4	0	0	none	n/a	80
					Male	Caucasian (White)	Melanoma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

TRUNK, per TSS.

ICD-O-3

Melanoma, malignant NOS

8720/3

Site: Skin trunk

C44.5

gw 4/2/13

UUID: FDSF5903-7586-4388-970A-36FBE8AE473D

Dual/Syn. vs. Primary: Not a		✓
Core is (circle):	DISQUALIFIED	

Source: NCI Genomic Data Commons file fe0b3173-887e-41c1-a34a-3174fd14267f (TCGA-BF-A5EO.FD5F5903-7586-4388-970A-36FBE8AE473D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).